Somatic mutation profile of tumor specimen TCGA-KN-8434-01A (aliquot TCGA-KN-8434-01A-11D-2310-10) from TCGA case TCGA-KN-8434, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 65.5 years (23,934 days).
Specimen TCGA-KN-8434-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b312598-841f-4b3d-a50f-2ee5a0b4bfdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8434-11A (Solid Tissue Normal), aliquot TCGA-KN-8434-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/037d1de1-4703-4c5d-b918-cd23a8909198

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, 3'UTR 3, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 24/41 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BIRC6 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.171); catalogued as COSV101429383; called by muse, mutect2
- FOXI1 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60389044, COSV60390308; called by muse, mutect2, varscan2
- GATA1 | c.949C>G p.R317G | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100936887; called by muse, mutect2
- LPIN2 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs146067222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF103 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99410448; called by muse, mutect2
- SHBG | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 32/51 reads (63%) | catalogued as rs745807575, COSV52646360; called by muse, mutect2, varscan2
- TMIGD3 | c.576C>A p.N192K (on ENST00000369717 / NM_001081976.2; = p.N273K on NM_020683.7) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs753140333; called by muse, mutect2, varscan2
- XYLT1 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180844430, COSV54480091; called by muse, mutect2, varscan2
- CC2D1A | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCLO | c.12601T>A p.S4201T | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SENP5 | c.1090_1092del p.P364del | In Frame Del (DEL) | VAF 46/114 reads (40%) | called by mutect2, pindel, varscan2
- TBC1D13 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TBC1D5 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ABCG4 | c.258G>A p.K86= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, varscan2
- AUTS2 | c.1650C>T p.I550= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs374492620; called by muse, mutect2, varscan2
- C9orf131 | c.2127G>A p.V709= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as rs909455160; called by muse, mutect2, varscan2
- CDC42BPG | c.2889G>T p.R963= | Silent (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- SLC26A6 | c.501C>T p.N167= | Silent (SNP) | VAF 61/159 reads (38%) | catalogued as rs146756914; called by muse, mutect2, varscan2
- TBC1D25 | c.1053C>A p.A351= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- ACTL7A | c.*84C>T | 3'UTR (SNP) | VAF 3/25 reads (12%) | catalogued as rs1179664430, COSV100453266; called by muse, mutect2
- CCDC184 | c.*475G>A | 3'UTR (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100344056; called by muse, mutect2, varscan2
- VWA1 | c.*487G>A | 3'UTR (SNP) | VAF 33/64 reads (52%) | catalogued as COSV100100843; called by muse, mutect2, varscan2
